Somatic mutation profile of tumor specimen 0DH5VN from CCDI case PBBNIJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Myxoid liposarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 18.8 years (6,868 days).
Specimen 0DH5VN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f30d1606-8a28-40fb-b605-242142f2c2a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH5UC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96ac8c8f-9ea0-4fb9-a8d2-11d3c7e6e1ba

The open-access MAF lists 13 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 3, 5'Flank 2, Intron 2, 3'Flank 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAGEC1 | c.187T>A p.S63T | Missense Mutation (SNP) | VAF 131/457 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as COSV53581658; called by muse, mutect2, varscan2
- PHC3 | c.2674C>T p.R892C (on ENST00000494943 / NM_001308116.2; = p.R904C on NM_024947.4) | Missense Mutation (SNP) | VAF 190/731 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs944861836, COSV71948386; called by muse, mutect2, varscan2
- SMG6 | c.1100G>C p.R367T | Missense Mutation (SNP) | VAF 226/708 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZKSCAN7 | c.555T>A p.Y185* | Nonsense Mutation (SNP) | VAF 33/896 reads (4%) | called by muse, mutect2
- ALB | c.342C>T p.C114= | Silent (SNP) | VAF 46/798 reads (6%) | called by muse, mutect2
- PPP2R1A | c.408G>A p.A136= | Silent (SNP) | VAF 36/632 reads (6%) | catalogued as rs748386684; called by muse, mutect2
- SELL | c.165T>C p.H55= (on ENST00000650983; = p.H42= on NM_000655.5) | Silent (SNP) | VAF 34/786 reads (4%) | catalogued as COSV52551509; called by muse, mutect2
- CGREF1 | chr2:27099178 C>T | 3'Flank (SNP) | VAF 26/396 reads (7%) | called by muse, mutect2
- EYS | c.1767-7617G>A | Intron (SNP) | VAF 53/167 reads (32%) | called by mutect2, varscan2
- IGFBP7 | chr4:57110889 T>A | 5'Flank (SNP) | VAF 53/205 reads (26%) | called by muse, mutect2, varscan2
- RAC2 | c.-2C>T | 5'UTR (SNP) | VAF 25/817 reads (3%) | called by muse, mutect2
- S1PR3 | chr9:88990899 A>C | 5'Flank (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2
- TAP2 | c.1461+10A>G | Intron (SNP) | VAF 302/1041 reads (29%) | called by muse, mutect2, varscan2
